CPTAC case C3N-01515 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1a53c571-af1d-4c79-be44-180cc79e0d4f

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1943; Vital status: Dead; Days to death: 19 days; Year of death: 2017; Cause of death: Cancer Related; Country of birth: United States.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Frontal lobe; Age at diagnosis: 73.8 years (26,969 days); Year of diagnosis: 2017; Last known disease status: With tumor; Days to last known disease status: 19 days; Progression or recurrence: no; Days to last follow up: 19 days.
   Pathology details: Greatest tumor dimension: 1.5 cm.

Follow-up (1 entry)
- Days to follow up: 19 days; Disease response: With Tumor; Karnofsky performance status: 0.

Other clinical attributes
- Weight: 71 kg; Height: 160 cm; BMI: 27.73.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 1; Cigarettes per day: 2; Tobacco smoking onset year: 1960; Tobacco smoking quit year: 1970; Alcohol history: Yes; Alcohol intensity: Heavy Drinker; Exposure duration years: 10.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-01515-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 275 mg; Time between excision and freezing: 11 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-01515-21: Section location: Frontal Lobe; Percent tumor nuclei: 70; Percent necrosis: 25.
- Sample C3N-01515-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
- Sample C3N-01515-32: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC).
